Gene-level copy-number profile of tumor specimen TCGA-2Y-A9H2-01A from TCGA case TCGA-2Y-A9H2, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 64.8 years (23,653 days).
Specimen TCGA-2Y-A9H2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.d8c203e8-f796-4f13-bc59-a7f49d5611ab.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-2Y-A9H2-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/24f9f3c7-b946-4ad2-8098-cf2b5178ac3f

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 904; copy number 2: 8,569; copy number 3: 12,642; copy number 4: 15,773; copy number 5: 12,793; copy number 6: 3,521; copy number 7: 4,098; copy number 8: 1,485; copy number 9: 16; copy number 10: 15; copy number 11: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-2Y-A9H2-01A-12D-A381-01): tumor purity 0.54, ploidy 4.05, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 34 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:160,608,106–160,647,295, 1 gene, copy number 10 (within-gene range 7–10): SLAMF1.
- chr2:108,247,195–108,318,611, 4 genes, copy number 10: SULT1C3, WASF1P1, SULT1C2, SULT1C2P2.
- chr2:144,666,312–146,194,821, 15 genes, copy number 9: TEX41, AC023128.1, AC023128.2, SGCEP1, LINC01966, AC096666.1, RPL6P5, AC092484.1, AC079163.2, AC079163.1, METAP2P1, AC079248.1, AC079248.2, RNU7-2P, RPL17P12.
- chr2:156,777,706–156,891,160, 3 genes, copy number 10: RPLP0P7, AC096589.2, AC096589.1.
- chr4:77,216,416–77,216,878, 1 gene, copy number 9: AC008638.3.
- chr6:39,934,595–40,000,527, 2 genes, copy number 11 (within-gene range 6–11): TUBBP9, FO393411.1.
- chr7:62,275,361–62,275,678, 1 gene, copy number 11: AC128676.1.
- chr8:137,105,352–137,425,021, 2 genes, copy number 10: RNU6-144P, ZYXP1.
- chr8:139,096,305–139,508,971, 5 genes, copy number 10: AC027541.1, AC100807.1, AC100807.2, AC087354.1, AC090093.1.

Autosomal genes at a single copy (total copy number 1): 904. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
